Somatic mutation profile of tumor specimen TCGA-3B-A9I0-01A (aliquot TCGA-3B-A9I0-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9I0, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 33.3 years (12,148 days).
Specimen TCGA-3B-A9I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58c48f10-5e22-4c93-bb8d-5e64f97898c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9I0-10A (Blood Derived Normal), aliquot TCGA-3B-A9I0-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0129a73e-644f-4933-9744-943a2006391c

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 19, Silent 3, Nonsense Mutation 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.576_578del p.Q192del | In Frame Del (DEL) | VAF 27/36 reads (75%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AQP4 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV101270516; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- DHX29 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as rs773832781, COSV99287271; called by muse, mutect2, varscan2
- DPT | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs200918644; called by muse, varscan2
- FUT10 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs1360740747, COSV100161428; called by muse, mutect2, varscan2
- KCNJ15 | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1023794725, COSV100154199; called by muse, mutect2, varscan2
- KIF22 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs769692085, COSV99361122; called by muse, mutect2, varscan2
- MTUS1 | c.363T>G p.C121W | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100029400; called by muse, mutect2, varscan2
- NOTCH4 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766255732, COSV66685328; called by muse, mutect2, varscan2
- PAX1 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV101270295; called by muse, mutect2, varscan2
- PCDHGA9 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99537908; called by muse, mutect2, varscan2
- PTPRK | c.4064T>A p.I1355K (on ENST00000368215 / NM_001291984.2; = p.I1356K on NM_002844.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100951037; called by muse, mutect2, varscan2
- RB1 | c.465T>A p.Y155* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV57294391, COSV57296545; called by muse, mutect2, varscan2
- RHO | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as COSV99078715, COSV99960614; called by muse, mutect2, varscan2
- SBNO2 | c.2808G>C p.R936= | Splice Region (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100684486; called by muse, mutect2, varscan2
- SERINC1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs200633097, COSV100305200; called by muse, mutect2, varscan2
- SETD1A | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99352938; called by muse, mutect2, varscan2
- TMEM51 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV101051524, COSV65690346; called by muse, mutect2, varscan2
- ZBTB3 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.055); catalogued as COSV101188959; called by muse, mutect2
- ZNF446 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs376903864; called by muse, mutect2, varscan2
- ZNF799 | c.1338G>C p.E446D | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV101345260; called by muse, mutect2
- BCAR3 | c.1902G>A p.A634= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs776696865, COSV53073053; called by muse, mutect2, varscan2
- CDH19 | c.318T>C p.D106= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs771478259, COSV100051540; called by muse, varscan2
- ZNF780B | c.879T>A p.I293= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99665674; called by mutect2, varscan2
